CCDI case PBCUMP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/90dc9528-f562-468a-89b8-f59d6b4a9d76

Demographics
Sex at birth: female.

Biospecimens (3 samples)
- Sample 0E03UL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0E03V9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E03W2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
